FM case AD4110 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/81b7677d-6079-4816-bb86-070558f02e3b

Female, 49.8 years: Carcinoma, NOS (ICD-O-3 8010/3) of the bladder; primary biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
